FM case AD8482 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/fd7cf6e8-9b07-43a8-b6f0-87fa5316401a

Male, 73.9 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the duodenum. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
